Somatic mutation profile of tumor specimen TCGA-AB-2858-03D (aliquot TCGA-AB-2858-03D-01W-0755-09) from TCGA case TCGA-AB-2858, project TCGA-LAML (Acute Myeloid Leukemia). Sex at birth: female; Vital status: Dead; Primary diagnosis: Acute myeloid leukemia with maturation; Tissue or organ of origin: Bone marrow; Age at diagnosis: 75.4 years (27,547 days).
Specimen TCGA-AB-2858-03D: Sample type: Primary Blood Derived Cancer - Peripheral Blood; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Peripheral Blood NOS.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d3fc4691-11d5-417b-bcee-3fdae52981c7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-AB-2858-12A (Buccal Cell Normal), aliquot TCGA-AB-2858-12A-01W-0755-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/682fbd4c-6291-4ced-a1e3-d8ae6e95ec1f

The open-access MAF lists 9 somatic variants for this specimen: 7 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 5, Silent 2, Nonsense Mutation 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AHNAK2 | c.3768G>T p.M1256I | Missense Mutation (SNP) | VAF 8/94 reads (9%) | SIFT tolerated (0.26); PolyPhen benign (0.101); catalogued as COSV100318949; called by muse, mutect2
- CFAP54 | c.7945G>A p.G2649R | Missense Mutation (SNP) | VAF 15/54 reads (28%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.849); catalogued as rs1297078253, COSV61572419, COSV61574250; called by mutect2, varscan2
- GRIK4 | c.2125G>A p.G709R | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV101483853; called by muse, varscan2
- NFE2L1 | c.485dup p.V163Sfs*14 | Frame Shift Ins (INS) | VAF 7/33 reads (21%) | catalogued as rs773403681; called by mutect2, varscan2
- RAPGEF2 | c.469G>T p.E157* | Nonsense Mutation (SNP) | VAF 27/93 reads (29%) | catalogued as COSV100031765; called by muse, mutect2, varscan2
- SMC1A | c.3358A>G p.K1120E | Missense Mutation (SNP) | VAF 30/83 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100447717; called by muse, mutect2, varscan2
- ZNF84 | c.106G>A p.V36M | Missense Mutation (SNP) | VAF 14/176 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV59654761; called by muse, mutect2
- CNOT1 | c.696G>A p.R232= | Silent (SNP) | VAF 4/13 reads (31%) | called by mutect2, varscan2
- DPPA2 | c.18G>A p.L6= | Silent (SNP) | VAF 43/154 reads (28%) | catalogued as rs191315064, COSV101524740, COSV101524801; called by muse, mutect2, varscan2
